Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA87, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA87-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD-O-3
Carcinoma, urothelial NOS
812013

Site: Bladder NOS
C67.9

QW 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

1 - "Left ureteral margin, paraffin from preoperative exam:
Free of neoplastic involvement.

2 - "Right ureteral margin, paraffin from preoperative exam:
Free of neoplastic involvement.

3 - "Prostate + bladder":

High-grade urothelial carcinoma of the bladder characterized as follows:

Measure of neoplasia in its major axis: 6.5 cm.

Ulceration present.

Extensive areas of necrosis.

Involvement of:

bladder.

all prostate

right seminal vesicle and

fibroadipous peri-visceral connective tissue.

Neural infiltration present.

Lymphatic vascular invasion doubtful.

Sanguineous vascular invasion not detected.

Surgical margins free of neoplastic involvement.

4 - "Left lymphadenectomy":

Free of neoplastic involvement (0/3).

5 - "Right lymphadenectomy":

Free of neoplastic involvement (0/2).

Source: NCI Genomic Data Commons file 02d89b0d-8bd7-4219-af20-3ac901064f22 (TCGA-4Z-AA87.0B1A1E8B-78FD-43B8-A6B1-2E7EB251FD52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).